CCDI case PBCIKM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/3042e9dd-a487-424b-aab5-4db3e6492664

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Dermatofibrosarcoma protuberans, NOS: ICD-O-3 morphology code: 8832/3; Tissue or organ of origin: Skin of lower limb and hip; Age at diagnosis: 15.0 years (5,476 days).

Biospecimens (3 samples)
- Sample 0DSR4T: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSR4Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSR5A: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
